Surgical pathology report (de-identified scan), TCGA case TCGA-CD-8526, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-8526-01A (Primary Tumor).

[page 1 of 5]
Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints: Abdominal pain ; nausea Sometimes vomit

Symptoms: Weight loss ..

Clinical Findings:

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☒ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)		
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /
				/ /	To	/ /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY	
Menopausal Status ☐ Pre-menopausal ☐ Peri-Menopausal ☒ Post-menopausal	Date of First Menses Don't remember Date of Last Menses Don't remember
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:	☐ Hormone Replacement Therapy:

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:	
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:	
Hep C	☒ Negative ☐ Positive:		CA 19-9	☐ Negative ☐ Positive:	
AFP	☐ Negative ☐ Positive:		PSA	☐ Negative ☐ Positive:	
Other:	☐ Negative ☐ Positive:		Other:	☐ Negative ☐ Positive:	
B/T Cell Markers:					

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy ✓	A lesion at the pylorus	
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	
T ₃ N ₁ M ₀	Stage: III

Treatment Information

SURGICAL TREATMENT			
Procedure		Date of Procedure	
Extended Gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach Tumor	Lesser Curvature	6 x 5 x 2 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T ₃ N ₁ M ₀		Stage: III	

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
11 min		12 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Stomach tumor	6 x 5 x 2 cm	lesser curvature	6 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3 N 1 M 0		Stage: III	

Notes:

Stomach nodes 2 (positive)

[page 5 of 5]
1. *Histological pattern:*

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse			✓	Streaming			
Mosaic		✓		Storiform			
Necrosis		✓		Fibrosis			
Lymphocytic Infiltration		✓		Palisading			
Vascular Invasion			✓	Cystic Degeneration			
Clusterized		✓		Bleeding			
Alveolar Formation			✓	Myxoid Change			
Indian File			✓	Psammoma/Calcification			

2. *Cellular features:*

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell	✓		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	✓		Fibroblast			Small Cell		
Keratin			Secretion	✓		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	✓		Lipoblast			Inflam. Cell		
Pearl			Gland formation	✓		Myoblast			Plasma Cell		

Otherwise Specified:

D, 70%, D2 50%, D3 80%, D4 60%, Necrosis 2%

2. *Cellular Differentiation:*

Well	Moderately	Poor
		✓

3. *Nuclear Atypia:*

Nuclear Appearance		0	I	II	III
Aniso Nucleosis					✓
Hyperchromatism				✓	
Nucleolar Prominent				✓	
Multinucleated Giant Cell					✓
Mitotic Activity					✓
Nuclear Grade					✓

Source: NCI Genomic Data Commons file 4729b75a-d980-4073-a53f-984b25e53588 (TCGA-CD-8526.67E3FE30-EBF2-43FC-853F-9DBFC5EB3A56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).